CCDI case PBCMZN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/94aaeaf5-3df7-4af6-b4c8-4178731ddf43

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,913 days).

Biospecimens (3 samples)
- Sample 0DVKDP: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVKDZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVKEI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
